CCDI case PBCGZE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/19ca62cb-029f-4dd9-bf2a-036a10586371

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Descending colon; Age at diagnosis: 15.9 years (5,791 days).

Biospecimens (3 samples)
- Sample 0DRQSS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRQT4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRQTD: Tissue type: Tumor; Specimen type: Solid Tissue.
